Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAM4, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAM4-01A (Primary Tumor).

[page 1 of 2]
Concerning

Summary pathology report

Left orchidectomy; nonseminoma (YST 95%, MT+IT 5%) diameter 2.5 cm; no angio-invasion;
invasion of rete testis unknown; tumor confined to testis.

Date of procurement (= date of orchidectomy):

ICD-O-3
Tumor, yolk sac 9071/3
Site @ Testis NOS C62.9
JAS 8/5/14

pathologist

professor of pathology

TCGA Tumor is:
yolk sac 90%
mature teratoma 5%
immature teratoma 5%

Pw TSS dx discrepancy form.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	YST (95%), MT plus IT (5%) _____	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	YST (90%), MT (5%), IT (5%) _____	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Due to the histological heterogeneous constitution of non-seminomas, the representation of the different elements can and is in fact expected to differ between the FFPE and frozen samples of the same case. However, the components are monoclonal in origin.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 2868f879-e438-414c-8760-14fd160f9022 (TCGA-2G-AAM4.8CD1C43E-8DA8-4CB3-B082-F368BB1D59CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).